Somatic mutation profile of tumor specimen MMRF_1664_1_BM_CD138pos (aliquot MMRF_1664_1_BM_CD138pos_T1_KBS5U_L04813) from MMRF case MMRF_1664, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.9 years (23,322 days).
Specimen MMRF_1664_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89cd9137-121e-4633-992b-861c3216b47e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1664_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1664_1_PB_Whole_C3_KBS5U_L04825; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94223aa4-f5e5-4c57-bd04-7e6b5951a857

The open-access MAF lists 55 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 14, Intron 7, Silent 3, 5'UTR 2, Frame Shift Del 1, Splice Region 1, RNA 1, Nonsense Mutation 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY10 | c.3464G>A p.R1155K | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV63243981; called by muse, mutect2, varscan2
- CCDC180 | c.3149C>G p.A1050G | Missense Mutation (SNP) | VAF 182/395 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100826595; called by mutect2, varscan2
- EVI2A | c.490T>A p.S164T | Missense Mutation (SNP) | VAF 100/190 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99907633; called by muse, mutect2, varscan2
- INHBB | c.816C>G p.H272Q | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs747008552; called by muse, mutect2, varscan2
- KCNN1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs1271360310; called by mutect2, varscan2
- MYOM3 | c.1970+4C>T | Splice Region (SNP) | VAF 31/63 reads (49%) | catalogued as rs746411932, COSV58391067; called by muse, mutect2, varscan2
- TAOK1 | c.1475A>G p.H492R | Missense Mutation (SNP) | VAF 115/233 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as rs1224531763; called by muse, mutect2, varscan2
- ADGRB1 | c.1966G>A p.G656R | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMT1 | c.841T>C p.Y281H | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPT1B | c.1352+1G>C p.X451_splice | Splice Site (SNP) | VAF 29/41 reads (71%) | called by muse, mutect2, varscan2
- FGFR3 | c.823T>G p.C275G | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXN4 | c.198C>A p.D66E | Missense Mutation (SNP) | VAF 90/183 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HOXD8 | c.870T>A p.N290K | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- IGHV2-70D | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 51/52 reads (98%) | SIFT tolerated (1); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- IMPACT | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KCNN2 | c.391C>A p.R131S (on ENST00000264773; = p.R343S on NM_021614.4) | Missense Mutation (SNP) | VAF 164/335 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCORL | c.5140G>C p.V1714L | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- MECOM | c.77G>C p.C26S (on ENST00000468789 / NM_001105078.4; = p.C214S on NM_004991.4) | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEGF6 | c.1733_1734del p.S578Cfs*15 | Frame Shift Del (DEL) | VAF 103/290 reads (36%) | called by pindel, varscan2
- NOS1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- POT1 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- PPARGC1A | c.569G>A p.S190N | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.45); called by muse, mutect2
- PROC | c.203A>C p.E68A | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINE2 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SNORC | c.219G>T p.E73D | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SPRING1 | c.26G>A p.W9* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2
- VAV1 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CHRNA2 | c.1113G>A p.L371= | Silent (SNP) | VAF 58/134 reads (43%) | called by muse, mutect2, varscan2
- POM121L12 | c.585G>A p.P195= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as rs781667306, COSV68692555; called by muse, mutect2
- RUNX1 | c.657G>A p.T219= (on ENST00000344691 / NM_001001890.3; = p.T246= on NM_001754.5) | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs546998294; called by muse, mutect2, varscan2
- AC103796.1 | n.148-25275G>T | Intron (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- AFAP1 | c.1646-105C>A | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- AP003548.1 | n.469G>T | RNA (SNP) | VAF 144/332 reads (43%) | called by muse, mutect2, varscan2
- ATAD2B | c.*2751A>T | 3'UTR (SNP) | VAF 52/105 reads (50%) | catalogued as rs1009332194; called by muse, mutect2, varscan2
- CLN6 | c.297+139A>T | Intron (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- CRTC3 | c.*483C>T | 3'UTR (SNP) | VAF 102/262 reads (39%) | called by muse, mutect2
- DOK7 | c.*719C>A | 3'UTR (SNP) | VAF 22/96 reads (23%) | called by muse, mutect2, varscan2
- EID1 | c.-20G>C | 5'UTR (SNP) | VAF 27/65 reads (42%) | catalogued as rs1324467694; called by muse, mutect2, varscan2
- EPHA3 | c.*56C>T | 3'UTR (SNP) | VAF 50/111 reads (45%) | catalogued as rs955347666, COSV60698517; called by muse, mutect2, varscan2
- EYA3 | c.*2329C>A | 3'UTR (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- FGFR3 | c.*185dup | 3'UTR (INS) | VAF 9/104 reads (9%) | called by mutect2, pindel
- G3BP1 | c.95+1152_95+1153insCAATACTGGTTTT | Intron (INS) | VAF 4/23 reads (17%) | catalogued as rs147540927; called by mutect2, varscan2
- GYS2 | c.*245A>G | 3'UTR (SNP) | VAF 32/87 reads (37%) | catalogued as rs774080324; called by muse, mutect2, varscan2
- ITCH | chr20:34508898 A>G | 3'Flank (SNP) | VAF 9/58 reads (16%) | catalogued as rs952045215; called by muse, mutect2, varscan2
- MID1 | c.*209dup | 3'UTR (INS) | VAF 62/70 reads (89%) | called by mutect2, varscan2
- NAP1L1 | c.*214G>A | 3'UTR (SNP) | VAF 189/426 reads (44%) | catalogued as rs1010059256; called by muse, mutect2, varscan2
- PDZRN3 | c.919-29256T>G | Intron (SNP) | VAF 87/195 reads (45%) | called by muse, mutect2, varscan2
- PKNOX1 | c.721-126T>A | Intron (SNP) | VAF 127/339 reads (37%) | called by muse, mutect2, varscan2
- PRKN | c.*1260C>A | 3'UTR (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- RNF38 | c.*2738C>T | 3'UTR (SNP) | VAF 49/161 reads (30%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.-279C>T | 5'UTR (SNP) | VAF 69/138 reads (50%) | called by muse, mutect2, varscan2
- SLITRK3 | c.*1060T>C | 3'UTR (SNP) | VAF 72/155 reads (46%) | catalogued as COSV99579946; called by muse, mutect2, varscan2
- ST14 | c.*239C>A | 3'UTR (SNP) | VAF 32/82 reads (39%) | called by muse, varscan2
- SYT10 | c.*1046G>T | 3'UTR (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- ZBTB17 | c.1371+48G>A | Intron (SNP) | VAF 46/90 reads (51%) | catalogued as rs891528921; called by muse, mutect2, varscan2
